Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A1HT, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A1HT-01A (Primary Tumor).

[page 1 of 5]
1CD-0-3

Carcinoma, hepatocellular, NOS 8/70/3

Site: Liver C22.0 2/1/11

lw

IRB APPROVED

Form Revised

Clinical Case Report

(For Collection of Cancerous Tissue)

ID#:

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the

with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married		
☒ Male ☐ Female	54 kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			11/16	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; Fever
Symptoms: Weight loss; tired of eating
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☒ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
ID#:

PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☒ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 5]
ID#:

Pathology Form

Specimen Information

Collected by: _____ Date _____ Time _____
Preserved by: _____ Date _____ Time _____

SPECIMEN TYPE (# of samples provided)					
Frozen		Paraffin Block		Blood/Serum/Plasma	
Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2		
Time to LN2		Time to Formalin		Time to LN2	
12 min		13 min		min	

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver tumor	6 x 4x cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀		Stage: III	
Notes:			

[page 4 of 5]
ID#:

DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound ✓	A tumour was found in the liver	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging	Date of Diagnosis	
T3 N0 M0 Stage: IIA		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Hepatic Resection			
Primary Tumor			
Organ	Detailed Location	Size	
Liver Tumor	Right	6 x 4 x cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: III			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic		☒	Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration		☒	Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized		☒	Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Pseudomembrane/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation		☒	Myoblast			Plasma Cell		
Otherwise Specified: D1 75% D2 50% D3 60% D4 0%											

2. Cellular Differentiation:

Well	Moderately	Poor
		☒

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			☒	☒
Hyperchromatism			☒	☒
Nucleolar Prominent			☒	☒
Multinucleated Giant Cell			☒	☒
Mitotic Activity			☒	☒
Nuclear Grade			☒	☒

Histological Diagnosis: Hepatocellular Carcinoma, G3

Comments: D4 : Cancer 0% Rejected

Date

Source: NCI Genomic Data Commons file cf9009c1-8360-461c-ad35-4ffc92f0a1e5 (TCGA-CC-A1HT.81F0F911-C2C1-48AD-A67F-FD455503CB46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).